Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A8SA, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A8SA-01A (Primary Tumor).

[page 1 of 2]
PROSTATE AND OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

TUMOR PROCUREMENT:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

OTHER (SPECIFY): _INTRADUCTAL CRIBRIFORM COMPONENT

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 4 = 8

TERTIARY PATTERN 5

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

1: ___%

2: ___%

3: ___%

4: 95%

5: 5%

TUMOR LOCATION

APEX

MID

BASE

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

NON-FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

POSTERIOR

LEFT

SEMINAL VESICAL INVASION

PRESENT

LEFT

SURGICAL MARGINS

INVOLVED BY INVASIVE CARCINOMA

POSTERIOR

LEFT

NATURE OF POSITIVE MARGINS

IN AREAS OF INTRA-PROSTATIC INCISION

EXTENT OF POSITIVE MARGINS

MULTIFOCAL

MILLIMETRIC EXTENT OF POSITIVE MARGINS: NOT REPORTED

GLEASON GRADE OF CARCINOMA PRESENT AT THE POSITIVE MARGINS

NOT REPORTED

LYMPHOVASCULAR INVASION

ABSENT

PERINEURAL INVASION

PRESENT

TUMOR VOLUME

DOMINANT NODULE: 4x1.5x1.44= 8.64cm³

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

RIGHT OBTURATOR

NUMBER OF NODES IDENTIFIED: _6_

NUMBER OF NODES INVOLVED BY METASTASIS: _0_

LEFT OBTURATOR

LCDD-3

Adenocarcinoma NOS 814013

Site: Prostate NOS 0619

9/12/14

[page 2 of 2]
NUMBER OF NODES IDENTIFIED: 3

NUMBER OF NODES INVOLVED BY METASTASIS: 0

ADDITIONAL PATHOLOGIC FINDINGS

OTHERS: Intraductal cribriform component (Immunohistochemistry: basal cells CK903+)

PATHOLOGICAL STAGING

pT3b

pN0

pMX

Source: NCI Genomic Data Commons file 255b1934-86f3-4329-94e2-22bc1b3dfb60 (TCGA-YL-A8SA.F837EF53-FF44-4F51-8764-27B00168B113.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).